Gene-level copy-number profile of tumor specimen HCM-BROD-0596-C43-06A from HCMI case HCM-BROD-0596-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.7 years (25,087 days).
Specimen HCM-BROD-0596-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a2eb3eda-35d2-4b40-b088-471b912d4a63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0596-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/39dfd6b4-1ee2-4e90-a47f-07766168547e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 6; copy number 2: 1,161; copy number 3: 10,808; copy number 4: 18,139; copy number 5: 18,390; copy number 6: 4,653; copy number 7: 3,571; copy number 8: 1,488; copy number 15: 2; copy number 26: 57; copy number 32: 21; copy number 59: 39; copy number 61: 14; copy number 62: 33; copy number 119: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:36,165,681–36,176,636, 1 gene (within-gene range 0–4): TBC1D3B.
- chr17:36,210,924–36,234,554, 3 genes: CCL4L2, AC243829.5, AC243829.3.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 168 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,701,782, 133 genes, copy number 26–119 (within-gene range 5–119) (broad region; genes not listed).
- chr1:1,724,512–2,591,469, 35 genes, copy number 15–62 (within-gene range 5–62): AL031282.1, SLC35E2A, NADK, GNB1, AL109917.1, CALML6, TMEM52, CFAP74, AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
